Gene-level copy-number profile of tumor specimen TCGA-HZ-A8P1-01A from TCGA case TCGA-HZ-A8P1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 81.1 years (29,631 days).
Specimen TCGA-HZ-A8P1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.73318a71-7388-48d3-8cee-c62ce0e9854f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-A8P1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c507e6a4-3ba6-4e75-bcaf-ca4ecd2bd8f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,531; copy number 2: 44,073; copy number 3: 4,137; copy number 5: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-A8P1-01A-11D-A376-01): tumor purity 0.69, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
